Gene-level copy-number profile of specimen HCM-SANG-0292-C15-85A from HCMI case HCM-SANG-0292-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0292-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e9dbdae-33f1-4364-a03d-6bde778aeb4d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0292-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,749 have no estimate.
https://portal.gdc.cancer.gov/files/4a1e5a76-4e86-4fdb-8b4b-d19895e21a86

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 40; copy number 1: 2,801; copy number 2: 8,823; copy number 3: 25,307; copy number 4: 14,321; copy number 5: 3,239; copy number 6: 3,551; copy number 7: 238; copy number 8: 289; copy number 9: 28; copy number 10: 106; copy number 11: 37; copy number 12: 34; copy number 13: 2; copy number 27: 5; copy number 29: 5; copy number 33: 30; copy number 41: 1; copy number 43: 12; copy number 44: 4; copy number 57: 1.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:13,305,152–14,210,891, 40 genes: AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP, GXYLT1P2, CNN2P7, ZNF114P1, CYP4F29P, SNX18P13, ANKRD20A11P, RHOT1P2, RNU6-954P, NF1P3, PPP6R2P1, FRG2MP, AP001347.1, ANKRD20A18P, RNA5SP488, AP001347.2, LIPI, ERLEC1P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 792 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:174,919,082–177,610,330, 84 genes, copy number 8 (broad region; genes not listed).
- chr7:2,558,972–17,467,256, 218 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:5,072,645–5,716,804, 10 genes, copy number 7: AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2.
- chr8:37,405,439–37,554,183, 4 genes, copy number 7 (within-gene range 6–7): AC091182.2, LINC01605, AC124067.1, AC124067.2.
- chr8:39,522,976–39,580,134, 1 gene, copy number 7: AC123767.1.
- chr8:63,651,457–64,383,787, 7 genes, copy number 8 (within-gene range 2–8): AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2.
- chr8:64,798,804–67,746,378, 52 genes, copy number 7–11: AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:79,259,402–81,924,348, 68 genes, copy number 10–13 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 7: LINC02839.
- chr8:115,950,511–116,325,062, 1 gene, copy number 8 (within-gene range 2–8): LINC00536.
- chr8:116,289,622–128,564,679, 183 genes, copy number 8–9 (broad region; genes not listed).
- chr12:21,437,615–31,073,847, 163 genes, copy number 10–57 (within-gene range 4–57) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 527. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
